Somatic mutation profile of tumor specimen C3L-00090-01 (aliquot CPT0001140005) from CPTAC case C3L-00090, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.5 years (27,587 days).
Specimen C3L-00090-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d3ad52c-af9c-44c0-8ec9-46880a412de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00090-31 (Blood Derived Normal), aliquot CPT0000040163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a024bfd2-5d03-4588-91f4-1f8fbb590eea

The open-access MAF lists 91 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Intron 8, Nonsense Mutation 6, 5'UTR 3, 5'Flank 3, Frame Shift Del 2, In Frame Del 2, RNA 2, Splice Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 409/531 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs747664529; called by muse, mutect2, varscan2
- ADCY5 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs945526595; called by muse, mutect2, varscan2
- AKAP6 | c.5062C>G p.L1688V | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55227444; called by muse, mutect2
- ATG4A | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs768783011, COSV100619669; called by muse, mutect2, varscan2
- CACNA1E | c.4409G>A p.R1470H | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV62387568; called by muse, mutect2, varscan2
- CCL25 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV99495270; called by muse, mutect2, varscan2
- CHD6 | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58553262; called by muse, mutect2, varscan2
- EPHA10 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775380990; called by muse, mutect2, varscan2
- FAM81B | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 56/163 reads (34%) | catalogued as rs201323524; called by muse, mutect2, varscan2
- FERD3L | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51761884, COSV51762932; called by muse, mutect2, varscan2
- FRMPD3 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs768248131, COSV99346277; called by muse, mutect2, varscan2
- GRIK1 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389738147, COSV58717166; called by muse, mutect2
- HIVEP3 | c.6496G>A p.G2166S | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs754592498; called by muse, mutect2, varscan2
- INPP4A | c.1870+1G>A p.X624_splice (on ENST00000074304 / NM_001134224.1; = p.X585_splice on NM_001566.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 68/191 reads (36%) | catalogued as COSV50822828; called by muse, mutect2, varscan2
- JAKMIP3 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs778256713; called by muse, mutect2, varscan2
- LTBP3 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as rs200142302, COSV57241131; called by muse, mutect2
- METTL3 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52971230; called by muse, varscan2
- NFE2L1 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 119/340 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62583855; called by muse, mutect2, varscan2
- PRDM9 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 143/410 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs1449575614; called by muse, mutect2, varscan2
- PROM2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs879491950; called by muse, mutect2, varscan2
- PRPF8 | c.4774G>T p.D1592Y | Missense Mutation (SNP) | VAF 157/522 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59260109, COSV59267815; called by muse, mutect2, varscan2
- PTGIS | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs759208880, COSV54840031; called by muse, mutect2
- RGS20 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs141996990; called by muse, mutect2, varscan2
- RYR1 | c.6731G>A p.R2244Q | Missense Mutation (SNP) | VAF 178/554 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs551314025, COSV62104180; called by muse, mutect2, varscan2
- SARDH | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs757027231, COSV100061468; called by muse, varscan2
- SOX17 | c.1243T>C p.*415Rext*48 | Nonstop Mutation (SNP) | VAF 84/346 reads (24%) | catalogued as COSV99810931; called by muse, mutect2, varscan2
- THBS2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.264); catalogued as rs772477090; called by muse, mutect2, varscan2
- TM9SF4 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs576294059; called by muse, mutect2, varscan2
- USP24 | c.6655C>T p.R2219* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as rs769648756; called by muse, varscan2
- USP53 | c.1518T>A p.H506Q | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV56798334; called by muse, mutect2, varscan2
- ZFR2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs778392661; called by muse, mutect2, varscan2
- ADAT1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 203/566 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CFAP65 | c.3809C>A p.P1270Q | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DENND4B | c.1819G>A p.G607S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, varscan2
- FBXL13 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GABRA1 | c.414C>A p.N138K | Missense Mutation (SNP) | VAF 99/310 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALR3 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- HAPLN3 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- HNRNPM | c.18_29del p.A7_E10del | In Frame Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- INPP4A | c.1284C>A p.Y428* | Nonsense Mutation (SNP) | VAF 93/245 reads (38%) | called by muse, mutect2, varscan2
- ITGA8 | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNA7 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KLHL34 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MED13L | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 54/179 reads (30%) | called by muse, mutect2, varscan2
- METTL3 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MYO1H | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NIPBL | c.6867_6870del p.F2291Tfs*11 | Frame Shift Del (DEL) | VAF 120/313 reads (38%) | called by mutect2, pindel, varscan2
- NUP153 | c.1678_1680del p.S560del | In Frame Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- PCSK1N | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R1 | c.1761dup p.G588Rfs*14 (on ENST00000521381 / NM_181523.3; = p.G318Rfs*14 on NM_181504.4) | Frame Shift Ins (INS) | VAF 106/333 reads (32%) | called by mutect2, pindel, varscan2
- RABGAP1L | c.2331C>A p.C777* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- RTN4RL1 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SVIL | c.5485T>C p.S1829P (on ENST00000355867 / NM_021738.3; = p.S1403P on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/647 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- VEGFB | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YLPM1 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 99/311 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ZFP36L2 | c.265_272del p.S89Gfs*11 | Frame Shift Del (DEL) | VAF 42/180 reads (23%) | called by mutect2, pindel, varscan2
- ABCA7 | c.3711C>T p.R1237= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs535290674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUWE1 | c.2397G>T p.L799= | Silent (SNP) | VAF 22/297 reads (7%) | catalogued as rs1416684717; called by muse, mutect2
- KCNAB3 | c.24C>T p.T8= | Silent (SNP) | VAF 147/477 reads (31%) | catalogued as rs1379066430; called by muse, mutect2, varscan2
- MUC16 | c.7455C>T p.S2485= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs753211564; called by muse, mutect2, varscan2
- OR2T29 | c.18G>A p.R6= | Silent (SNP) | VAF 53/368 reads (14%) | catalogued as rs1240495811; called by muse, mutect2, varscan2
- OR2T5 | c.18G>A p.R6= | Silent (SNP) | VAF 18/62 reads (29%) | called by mutect2, varscan2
- RYR1 | c.13866C>T p.G4622= | Silent (SNP) | VAF 132/380 reads (35%) | catalogued as rs370369058, COSV62097189; called by muse, mutect2, varscan2
- RYR1 | c.14544C>T p.V4848= | Silent (SNP) | VAF 194/569 reads (34%) | catalogued as rs1300663668; called by muse, mutect2, varscan2
- SART1 | c.465C>T p.V155= | Silent (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- SLC1A3 | c.711T>C p.S237= | Silent (SNP) | VAF 137/392 reads (35%) | catalogued as rs192878413; ClinVar: benign; called by muse, mutect2, varscan2
- SOX17 | c.84C>T p.G28= | Silent (SNP) | VAF 116/220 reads (53%) | catalogued as rs1156843387; called by muse, mutect2, varscan2
- STAB1 | c.6603C>T p.H2201= | Silent (SNP) | VAF 85/207 reads (41%) | called by muse, mutect2, varscan2
- TBCE | c.87C>T p.V29= | Silent (SNP) | VAF 59/219 reads (27%) | catalogued as COSV64007044; called by muse, mutect2, varscan2
- TSC2 | c.3990G>A p.T1330= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as rs369943684; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- TSPYL1 | c.381T>C p.G127= | Silent (SNP) | VAF 137/458 reads (30%) | catalogued as rs748951760; called by muse, mutect2, varscan2
- ZKSCAN4 | c.204C>T p.R68= | Silent (SNP) | VAF 77/208 reads (37%) | called by muse, mutect2, varscan2
- ABCB9 | chr12:122978899 G>A | 5'Flank (SNP) | VAF 84/289 reads (29%) | catalogued as rs201495114, COSV54897226; called by muse, mutect2, varscan2
- AC008080.1 | n.554C>T | RNA (SNP) | VAF 62/181 reads (34%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40445569 G>A | 5'Flank (SNP) | VAF 39/138 reads (28%) | called by muse, mutect2, varscan2
- AL590867.2 | n.91G>A | RNA (SNP) | VAF 168/473 reads (36%) | called by muse, varscan2
- ANKRD11 | c.-59-7496dup | Intron (INS) | VAF 12/42 reads (29%) | catalogued as rs751670371; called by mutect2, varscan2
- CAP2 | c.637-2980G>A | Intron (SNP) | VAF 43/132 reads (33%) | catalogued as rs756498224; called by muse, mutect2, varscan2
- CEP295 | chr11:93731064 T>C | 3'Flank (SNP) | VAF 34/127 reads (27%) | called by muse, mutect2, varscan2
- DNM2 | c.1336-973G>A | Intron (SNP) | VAF 158/452 reads (35%) | catalogued as rs765822610; called by muse, mutect2, varscan2
- EPDR1 | c.-63C>T | 5'UTR (SNP) | VAF 55/169 reads (33%) | called by muse, mutect2, varscan2
- GRID1 | c.-3dup | 5'UTR (INS) | VAF 53/176 reads (30%) | called by mutect2, pindel, varscan2
- HBE1 | c.-267+74671C>T | Intron (SNP) | VAF 140/478 reads (29%) | catalogued as rs962040406, COSV66528318; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85554G>A | Intron (SNP) | VAF 111/293 reads (38%) | catalogued as rs1290581973; called by muse, mutect2, varscan2
- MID1 | c.-20C>A | 5'UTR (SNP) | VAF 90/327 reads (28%) | called by muse, mutect2, varscan2
- MUC20 | c.*10G>T | 3'UTR (SNP) | VAF 50/240 reads (21%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-962C>G | Intron (SNP) | VAF 133/385 reads (35%) | called by muse, varscan2
- SUPT20H | c.1592-221G>C | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- TRDV2 | chr14:22418386 del TC | 5'Flank (DEL) | VAF 63/179 reads (35%) | called by mutect2, pindel, varscan2
- ZNF385B | c.-155+221_-155+233del | Intron (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel
